Surgical pathology report (de-identified scan), TCGA case TCGA-SP-A6QF, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Health Network, specimen TCGA-SP-A6QF-01A (Primary Tumor).

LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
DOB: [REDACTED] Visit #: [REDACTED]
Gender: [REDACTED] Location: [REDACTED]
HCN: [REDACTED] Facility: [REDACTED]
Ordering MD: [REDACTED]
Copy To: MD

Specimen(s) Received

1. Adrenal: right adrenal gland

Diagnosis

Pheochromocytoma and clear cell adenoma arising in a nodular cortex - Adrenal gland, (right) adrenalectomy specimen

Electronically verified by:

Clinical History

right adrenal pheochromocytoma

Gross Description

The specimen container labeled with the patient's name and as "right adrenal gland" contains an adrenal gland with periadrenal fat; the specimen weighs 31.5 g and measures 8 x 4 x 2.5 cm. The surface is painted with silver nitrate. The fat is separated from the adrenal gland. The adrenal gland alone weighs 20 g. On section, the cut surface reveals two masses. The smaller is a peripheral, circumscribed, yellow, solid nodule that measures 0.7 x 0.6 x 0.6 cm. The larger is a circumscribed, solid, homogeneous red-brown nodule that measures 2.1 x 2.0 x 1.5 cm and is 1.5 cm from the smaller mass. The remaining adrenal parenchyma has a variegated appearance with several smaller demarcated yellow areas ranging from 0.1 to 0.3 cm. No gross abnormality is noted within the periadrenal fatty tissue. Representative mass and adrenal tissue is stored frozen. Representative sections are submitted as follows:

- 1A-C adrenal tissue to include the smaller mass in toto
- 1D-H representative sections of the larger mass
- 1I-L random sections

Source: NCI Genomic Data Commons file 4cd2ffc1-fb69-414a-8a7d-2f8cc470e836 (TCGA-SP-A6QF.322F9E7A-A7D1-4A0C-A6AF-94F074ADBEDA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).